OHSU case 1833 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/a2a7d67f-9f5f-467c-a770-bdb02cbd7a98

Biospecimens (1 sample)
- Sample 1782D: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
